Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A3PB, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A3PB-01A (Primary Tumor).

[page 1 of 4]
Sex

Specimen Description

procurement date:

Surgical Pathology Report

Patient Name:

Accession #:

Med. Rec #:

Submitting Physician:

Clinical History

Dysphagia, neck cyst.

1CD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS 673.9

hw
2/5/12

*****Final Pathologic Diagnosis*****

- A. Soft tissue, adjacent to thyroid gland, biopsy:
- Lymph node (1/1) with metastatic papillary carcinoma.
- B. Right retroperotid neck mass, biopsy:
- Lymph node (1/1) with metastatic papillary carcinoma.
- C. Paratracheal mass, biopsy:
- Lymph node (1/1) with metastatic papillary carcinoma.
- D. Right superior thyroid pole, hemithyroidectomy:
- Papillary thyroid carcinoma (see synoptic report).
- Mild lymphocytic thyroiditis.
- E. Mass adjacent to superior right thyroid pole, excision:
- Lymph node (1/1) with metastatic papillary carcinoma.
- F. Right upper jugular node, excision:
- Lymph node (1/1) with metastatic papillary carcinoma.
- G. Left thyroid lobe, hemithyroidectomy:
- Mild lymphocytic thyroiditis; no malignant tumor seen.
- H. Left paratracheal mass, excision:
- Lymph node (0/1) with sinus histiocytosis; no malignant tumor seen.
- Mature thyroid follicular tissue with no evidence of malignancy.

Electronically Signed By

*****Synoptic Report*****

[page 2 of 4]
SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: Total thyroidectomy.

Tumor location: Right lobe.

Tumor size: 1.0 x 0.7 x 0.6 cm.

Histologic type: Papillary thyroid carcinoma.

Tumor grade: Low-grade.

Lymphatic/vascular invasion: Not apparent.

Capsular invasion: tumor infiltrates focally the capsule into perithyroidal fat.

Tumor extent:

Confined to the thyroid: Yes.

Multifocal: No.

Invasion of thyroid cartilage or hyoid bone: No.

Infiltration of adjacent structures: No.

Lymph nodes:

Total number examined: 6

Sites/laterality: Bilateral.

Number positive: 5

Number negative: 1

Extranodal extension: No.

Additional pathologic findings: Mild lymphocytic thyroiditis

***The above synoptic report complies, in slightly modified form, with the guidelines of the

specimens*** for the reporting of cancer

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

AF1. Tissue adjacent to thyroid gland: (FROZEN SECTION PERFORMED)

- Papillary carcinoma, favor thyroid.

- Reviewed with

BF1. Right retroparotid neck mass: (FROZEN SECTION PERFORMED)

- Papillary carcinoma involving lymph nodes, likely metastatic thyroid carcinoma.

CF1. Paratracheal mass: (FROZEN SECTION PERFORMED)

- Papillary carcinoma involving lymph nodes, likely metastatic thyroid carcinoma.

DF1. Right superior thyroid pole: (FROZEN SECTION PERFORMED)

- Papillary carcinoma of the thyroid.

Examining pathologist

SPECIMEN(S) RECEIVED:

A: Soft tissue

[page 3 of 4]
B: Soft tissue
C: Soft tissue
D: Thyroid, REG
E: Soft tissue
F: Lymph node, thoracic,
G: Thyroid,
H:

GROSS DESCRIPTION:

The specimens are received in eight properly labeled containers with the patient's name and accession number.

A. The specimen is designated "tissue adjacent to thyroid gland" and consists of a 0.9 x 0.5 x 0.3 cm portion of tan, soft tissue. The specimen is entirely submitted for frozen section and resubmitted as received in cassette AF1.

B. The specimen is designated "right retroparotid neck mass" and consists of a 2.3 x 1.6 x 0.4 cm portion of tan-red, soft tissue. The specimen is entirely submitted for frozen section and resubmitted as received in cassette BF1.

C. The specimen is designated "paratracheal mass" and consists of a 0.7 x 0.6 x 0.2 cm portion of tan-red soft tissue. The specimen is entirely submitted for frozen section and resubmitted as received in cassette CF1.

D. The specimen is designated "right superior thyroid pole one stitch = superior pole two stitches = thyroid isthmus" and consists of 6.2 gram portion of thyroid that is 4.3 x 2.3 x 1.2 cm. The specimen is oriented with one stitch at the superior pole and two stitches at the thyroid isthmus. The specimen is inked per frozen section as follows: Anterior, yellow; posterior, black and isthmus, blue. The specimen is serially sectioned from superior to inferior. The cut surfaces contain a well-defined and well-circumscribed tan-white nodule at superior pole that is 1.0 x 0.7 x 0.6 cm. The nodule abuts the posterior and anterior thyroid capsule and comes to within 2.0 cm of the thyroid isthmus. A random section of the nodule is submitted for frozen section and resubmitted as received in cassette DF1. The remaining thyroid parenchyma is deep red and rubbery.

Summary of Cassettes: DF1, frozen section of nodule; D1, remainder of nodule; D2, shaved isthmus margin; D3, uninvolved thyroid

E. The specimen is designated "mass adjacent to superior right thyroid fold" and consists of a 1.2 x 1.0 x 0.8 cm tan-pink nodule that has a scant amount of attached adipose tissue. The nodule is inked black and bisected to reveal a 0.4 x 0.4 x 0.4 cm smooth-walled cyst containing a red-tinged clear, thin fluid.

F. The specimen is designated "right upper jugular node" and consists of a 1.0 x 0.7 x 0.5 cm gray-black nodule that has a scant amount of attached adipose tissue.

G. The specimen is designated "left thyroid lobe one stitch = superior pole two stitches = isthmus" and consists of a 9.5 gram left lobe of thyroid that is 5.0 x 2.5 x 2.5 cm. The specimen is oriented with a single stitch at the superior pole and a double stitch at the isthmus.

[page 4 of 4]
margin. The capsule of the thyroid contains a 3.0 x 0.8 cm area of disruption. The specimen is inked as follows: Anterior yellow, posterior black and isthmic margin blue. The specimen is serially sectioned from medial to lateral. The cut surfaces are deep red and rubbery with no discrete lesions identified.

Summary of Cassettes: G1, shaved isthmic margin; G2, isthmus; G3-4, two random sections of thyroid

H. The specimen is designated "left paratracheal mass" and consists of a 0.8 x 0.6 x 0.4 cm tan-red nodule with a small amount of attached adipose tissue. The nodule is inked black and entirely submitted for histologic examination.

Gross description by: [REDACTED]

Top of Page

Source: NCI Genomic Data Commons file e994c6ad-dcd3-459a-bc98-a1fbd07c58fd (TCGA-FE-A3PB.048187E7-2B37-490A-9005-09541CACDD84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).